Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A1HY, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A1HY-06A (Metastatic).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Procedures/Addenda Attached

1CD-0-3

Melanoma, Nos 8720/3

Site: lymph nodes, Nos C77.9 3/12/11 *lw*

Clinical History and Impression:

year old presents with mass right axilla FNA
Diagnosis recurrent melanoma

Specimen(s) Received:

- 1: RIGHT RADICAL AXILLARY LYMPH NODE DISSECTION
- 2: RIGHT AXILLARY LYMPH NODE

FINAL DIAGNOSIS

1) LYMPH NODES, RIGHT AXILLA, RADICAL DISSECTION:

- THREE OF TWENTY-THREE LYMPH NODES, POSITIVE FOR METASTATIC MELANOMA WITH EXTRACAPSULAR EXTENSION (3/23) INCLUDING A LARGE MATTED LYMPH NODE MEASURING 4.0 CM

2) LYMPH NODE, RIGHT AXILLA, EXCISION:

- ONE LYMPH, NEGATIVE FOR MALIGNANCY (0/1)

Pathologist: M.D., Ph.D.
* Report Electronically Signed Out *

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description: M.D. ; M.D.)

1) Received fresh, labeled with the patient's name, unit# and "right radical axillary lymph node dissection" is a 9.0 x 8.0 x 3.0 cm yellow fatty adipose tissue into which a surgical defect has been made to reveal a well circumscribed firm tan-yellow mass measuring 4.0 x 1.5 x 1.2 cm. This appears to be a positive lymph node. Representative sections of this node is submitted into cassettes 1 and 2. All other possible lymph nodes are dissected from the fat and submitted into cassettes 3-8.

2) Received fresh, labeled with the patient's name, unit# and "right axillary node" are multiple fragments of yellow fatty adipose tissue measuring in aggregate 1.9 x 1.5 x 1.0 cm. The entire specimen is submitted into one cassette.

Summary of Tissue Submitted for Microscopic Examination

	Block Detail			
	# Blocks	Designation	#	Description
Part 1) RIGHT RADICAL AXILLARY LYMPH NODE	8	L	(8)	L

I/PAA Discrepancy		X
Reviewed: KM	Date Reviewed: 3/12/11	lw

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Part 2] RIGHT AXILLARY LYMPH NODE	1	L	(1)	(No Description)
Total:	9			

Procedures/Addenda

MOLECULAR DIAGNOSTIC TESTS

Status: Signed Out

Pathologist:

M.D.

Ordered:

Reported:

Findings (Results)

PCR FOR IMMUNOGLOBULIN AND T CELL RECEPTOR GENE REARRANGEMENTS WAS PERFORMED ON 1-3

Clonal immunoglobulin heavy chain gene rearrangement IS NOT detected by PCR in this sample (polyclonal product) using a primer set targeting the FR2-VH and JH regions of the gene. The consensus primers () detect clonal rearrangements in approximately 80% of B-cell neoplasms.

Clonal immunoglobulin heavy chain gene rearrangement IS NOT detected by PCR in this sample (polyclonal product) using a primer set targeting the FR3-VH and JH regions of the gene. The consensus primers used in this assay detect clonal rearrangements in approximately 65% of B-cell neoplasms.

Clonal rearrangement of the T-cell receptor-gamma gene IS NOT (Polyclonal product) detected by multiplex PCR/capillary electrophoresis in this specimen using a primer set targeting J regions Jy and JyP 1/2 and V regions Vy 1-8 ()

Clonal rearrangement of the T-cell receptor-gamma gene IS NOT (Polyclonal product) detected by multiplex PCR/capillary electrophoresis in this specimen using a primer set targeting J regions Jy and JyP 1/2 and V regions Vy 9, 10

Clonal rearrangement of the T-cell receptor-gamma gene IS NOT (Polyclonal product) detected by multiplex PCR/capillary electrophoresis in this specimen using a primer set targeting J regions Jy and JyP 1/2 and V regions Vy 11

Amplification of a control gene (beta-globin/actin/GAPDH) confirmed the sample. Rearranged positive control samples and negative controls were parallel

Analytic specific reagent is used. This test was developed and its performance characteristics determined by the [redacted]. The test has not been cleared or approved by the U.S. Food and Drug Administration. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Interpretation

NEGATIVE FOR CLONAL HEAVY CHAIN IMMUNOGLOBULIN REARRANGEMENT.

NEGATIVE FOR CLONAL GAMMA T CELL RECEPTOR GENE REARRANGEMENT.

Source: NCI Genomic Data Commons file 67517bbd-f391-4e98-b033-5ce36d2adb57 (TCGA-DA-A1HY.ACCF42A2-F4C6-4B69-AF2B-BF158D58900C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).